MMRF case MMRF_2138 — Multiple Myeloma CoMMpass Study (MMRF-COMMPASS)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Plasma Cell Tumors; Primary site: Hematopoietic and reticuloendothelial systems. Index date (day 0 for every day count below): first treatment.
https://portal.gdc.cancer.gov/cases/824df027-ca96-4f79-9136-470953a154c9

Demographics
Sex at birth: male; Race: black or african american; Ethnicity: not hispanic or latino; Age at index: 81 years; Vital status: Alive.

Diagnoses (1)
1. Multiple myeloma: ICD-O-3 morphology code: 9732/3; Tissue or organ of origin: Bone marrow; Site of resection or biopsy: Bone marrow; Age at diagnosis: 81.5 years (29,779 days); ISS stage: I; Days to last known disease status: 904 days (2.5 years); Days to last follow up: 904 days (2.5 years).
   Treatment given: Therapeutic agents: Bortezomib; Regimen or line of therapy: First line of therapy; Days to treatment start: 1 day; Days to treatment end: 119 days.
   Treatment given: Therapeutic agents: Dexamethasone; Regimen or line of therapy: First line of therapy; Days to treatment start: 1 day.
   Treatment given: Therapeutic agents: Carfilzomib; Regimen or line of therapy: First line of therapy; Days to treatment start: 165 days; Days to treatment end: 567 days (1.6 years).
   Treatment given: Therapeutic agents: Elotuzumab + Lenalidomide; Regimen or line of therapy: Second line of therapy; Days to treatment start: 609 days (1.7 years).

Molecular and laboratory tests (laboratory values one line per visit day; values rounded to 3 significant figures where GDC's unit conversion carried more)
- Day -9 (ECOG 1): M Protein 1.12 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 0.4 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.4 mg/dL; Immunoglobulin G 19.4 g/L; Immunoglobulin A 2.14 g/L; Immunoglobulin M 0.35 g/L; Lactate Dehydrogenase 4.22 µkat/L; Hemoglobin 5.83 mmol/L; Leukocytes 4.5 ×10⁹/L; Absolute Neutrophil 1.4 ×10⁹/L; Platelets 65 ×10⁹/L; Creatinine 98.1 µmol/L; Blood Urea Nitrogen 7.85 mmol/L; Calcium 2.28 mmol/L; Albumin 38 g/L; Total Protein 7.3 g/dL; Glucose 4.35 mmol/L.
- Day 81 (ECOG 1): M Protein 1.11 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 463 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 75 mg/dL; Immunoglobulin G 16.7 g/L; Immunoglobulin A 1.89 g/L; Immunoglobulin M 0.34 g/L; Beta 2 Microglobulin 2.82 µg/mL; Hemoglobin 5.33 mmol/L; Leukocytes 6 ×10⁹/L; Absolute Neutrophil 1.9 ×10⁹/L; Platelets 41 ×10⁹/L; Creatinine 133 µmol/L; Blood Urea Nitrogen 10 mmol/L; Calcium 2.35 mmol/L; Albumin 38 g/L; Total Protein 7.3 g/dL; Glucose 4.57 mmol/L.
- Day 179 (ECOG 1): M Protein 0.91 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 434 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 102 mg/dL; Immunoglobulin G 14.9 g/L; Immunoglobulin A 2.08 g/L; Immunoglobulin M 0.41 g/L; Beta 2 Microglobulin 4.41 µg/mL; Hemoglobin 5.64 mmol/L; Leukocytes 7.3 ×10⁹/L; Absolute Neutrophil 2.3 ×10⁹/L; Platelets 29 ×10⁹/L; Creatinine 116 µmol/L; Blood Urea Nitrogen 5.36 mmol/L; Calcium 2.45 mmol/L; Albumin 38 g/L; Total Protein 7 g/dL; Glucose 4.62 mmol/L.
- Day 256 (ECOG 1): M Protein 1.01 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 2.63 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.95 mg/dL; Immunoglobulin G 14.9 g/L; Immunoglobulin A 1.97 g/L; Immunoglobulin M 0.36 g/L; Beta 2 Microglobulin 3 µg/mL; Lactate Dehydrogenase 3.73 µkat/L; Hemoglobin 5.77 mmol/L; Leukocytes 4.17 ×10⁹/L; Absolute Neutrophil 2.5 ×10⁹/L; Platelets 41 ×10⁹/L; Creatinine 111 µmol/L; Blood Urea Nitrogen 6.43 mmol/L; Calcium 2.33 mmol/L; Albumin 40 g/L; Total Protein 6.7 g/dL; Glucose 4.57 mmol/L.
- Day 347 (ECOG 1): M Protein 1.15 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 6.06 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.37 mg/dL; Immunoglobulin G 15.7 g/L; Immunoglobulin A 1.78 g/L; Immunoglobulin M 0.37 g/L; Beta 2 Microglobulin 4.29 µg/mL; Hemoglobin 5.95 mmol/L; Leukocytes 3.4 ×10⁹/L; Absolute Neutrophil 1.1 ×10⁹/L; Platelets 42 ×10⁹/L; Creatinine 123 µmol/L; Blood Urea Nitrogen 13.9 mmol/L; Calcium 2.28 mmol/L; Albumin 41 g/L; Total Protein 6.9 g/dL; Glucose 5.83 mmol/L.
- Day 455 (ECOG 1): M Protein 1.4 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 45 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 11.2 mg/dL; Immunoglobulin G 19.7 g/L; Immunoglobulin A 1.76 g/L; Immunoglobulin M 0.39 g/L; Beta 2 Microglobulin 3.15 µg/mL; Hemoglobin 6.32 mmol/L; Leukocytes 4.7 ×10⁹/L; Absolute Neutrophil 1.4 ×10⁹/L; Platelets 38 ×10⁹/L; Creatinine 103 µmol/L; Blood Urea Nitrogen 10.4 mmol/L; Calcium 2.28 mmol/L; Albumin 41 g/L; Total Protein 7.8 g/dL; Glucose 3.91 mmol/L.
- Day 525 (ECOG 1): M Protein 1.5 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 7.01 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.6 mg/dL; Immunoglobulin G 20 g/L; Immunoglobulin M 0.31 g/L; Hemoglobin 6.39 mmol/L; Leukocytes 4.4 ×10⁹/L; Absolute Neutrophil 1.3 ×10⁹/L; Platelets 73 ×10⁹/L; Creatinine 103 µmol/L; Blood Urea Nitrogen 9.64 mmol/L; Calcium 2.33 mmol/L; Albumin 40 g/L; Total Protein 8 g/dL; Glucose 5.72 mmol/L.
- Day 630 (ECOG 1): M Protein 1.67 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 4.1 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.44 mg/dL; Immunoglobulin A 1.67 g/L; Immunoglobulin M 0.41 g/L; Beta 2 Microglobulin 2.8 µg/mL; Hemoglobin 6.7 mmol/L; Leukocytes 3.9 ×10⁹/L; Absolute Neutrophil 1.2 ×10⁹/L; Platelets 44 ×10⁹/L; Creatinine 112 µmol/L; Blood Urea Nitrogen 9.64 mmol/L; Calcium 2.23 mmol/L; Albumin 39 g/L; Total Protein 7.4 g/dL; Glucose 6.27 mmol/L.
- Day 720 (ECOG 1): M Protein 1.6 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 4.47 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.32 mg/dL; Immunoglobulin G 25.1 g/L; Immunoglobulin A 1.25 g/L; Immunoglobulin M 0.31 g/L; Beta 2 Microglobulin 3.55 µg/mL; Hemoglobin 7.01 mmol/L; Leukocytes 5.3 ×10⁹/L; Absolute Neutrophil 1.5 ×10⁹/L; Platelets 40 ×10⁹/L; Creatinine 99.9 µmol/L; Blood Urea Nitrogen 9.64 mmol/L; Calcium 2.3 mmol/L; Albumin 39 g/L; Total Protein 7.6 g/dL; Glucose 5.28 mmol/L.
- Day 810 (ECOG 1): M Protein 1.14 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 8.17 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.97 mg/dL; Immunoglobulin G 16.4 g/L; Immunoglobulin A 1.34 g/L; Immunoglobulin M 0.26 g/L; Beta 2 Microglobulin 3.31 µg/mL; Hemoglobin 5.89 mmol/L; Leukocytes 2.5 ×10⁹/L; Absolute Neutrophil 0.9 ×10⁹/L; Platelets 24 ×10⁹/L; Creatinine 99.9 µmol/L; Blood Urea Nitrogen 6.43 mmol/L; Calcium 2.33 mmol/L; Albumin 40 g/L; Total Protein 7.1 g/dL; Glucose 6.88 mmol/L.
- Day 904 (ECOG 1): M Protein 1.04 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 4.28 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.65 mg/dL; Immunoglobulin G 15.1 g/L; Immunoglobulin A 1.34 g/L; Immunoglobulin M 0.23 g/L; Beta 2 Microglobulin 0.42 µg/mL; Hemoglobin 6.14 mmol/L; Leukocytes 6.2 ×10⁹/L; Absolute Neutrophil 2.3 ×10⁹/L; Platelets 45 ×10⁹/L; Creatinine 120 µmol/L; Blood Urea Nitrogen 7.85 mmol/L; Calcium 2.13 mmol/L; Albumin 35 g/L; Total Protein 7.3 g/dL; Glucose 6.38 mmol/L.

Other clinical attributes
- Day -9: Weight: 67 kg; Height: 157 cm.

Family history
- Relative with cancer history: no.

Biospecimens (2 samples)
- Sample MMRF_2138_1_BM_CD138pos: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS; Days to sample procurement: -9 days.
- Sample MMRF_2138_1_PB_Whole: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS; Days to sample procurement: -9 days.
